FM case AD12924 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/5d25a64b-287f-41de-a3cc-bc75470fadb9

Male, 47.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the head, face or neck; specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
